Surgical pathology report (de-identified scan), TCGA case TCGA-HR-A2OG, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HR-A2OG-06A (Metastatic).

lw 9/16/11

Sample Type Tumour Primary

Sample Preparation
Site of Primary (Event)
Site of Tissue
Year of Sample Collection
Age at Sample Collection (yrs)
Sample Comments
Days to Procedure Date
Days to Diagnosis
Type of Procedure
Site of Primary (Histology)
Recurrent Site
Tumour Diameter (mm)
Tumour Depth (mm)
Breslow Technique
Histology
Grade/Differentiation
Pathological T
Pathological N
Clinical M
Histology Comments

Fresh Frozen
Melanoma
Mass in thigh

0
20
Surgical resection
Unknown
NO
45
40
Unknown
Metastatic melanoma
Grade X (Unknown)
TX
NX
M1a
Tumour mass from anterior right thigh.

1CD-0-3

Melanoma, NOS 8720/3

Site: thigh, NOS 044.6

*lw
9/16/11*

Source: NCI Genomic Data Commons file b56df64b-1ca6-4c40-bf23-c650039ca266 (TCGA-HR-A2OG.08CD8EB8-B0B1-4328-92A8-C4AB10A38202.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).